Somatic mutation profile of tumor specimen TCGA-NC-A5HM-01A (aliquot TCGA-NC-A5HM-01A-12D-A26M-08) from TCGA case TCGA-NC-A5HM, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.5 years (27,938 days).
Specimen TCGA-NC-A5HM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad87ef9b-85be-45b6-9c77-e875e963a6f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HM-10A (Blood Derived Normal), aliquot TCGA-NC-A5HM-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98897368-142c-40d4-9f8e-3b0b36b40938

The open-access MAF lists 298 somatic variants for this specimen: 243 protein-altering or splice-affecting, 48 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 48, Nonsense Mutation 18, Frame Shift Del 8, Splice Site 4, Splice Region 3, Intron 3, In Frame Del 2, RNA 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as rs367543028, CM973008, COSV100757300; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2478G>C p.L826F | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100383387; called by muse, mutect2, varscan2
- ABCB5 | c.3429+2T>C p.X1143_splice (on ENST00000404938 / NM_001163941.2; = p.X698_splice on NM_178559.6) | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as rs373651350, COSV51712174; called by muse, mutect2, varscan2
- ABCD2 | c.953A>C p.Q318P | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.916); catalogued as COSV100429729; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV65891681, COSV65892012; called by muse, mutect2, varscan2
- ADGRB3 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV101001631; called by muse, mutect2, varscan2
- AFF3 | c.2840G>T p.R947L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV100419868; called by muse, mutect2, varscan2
- AGAP1 | c.2141C>T p.A714V (on ENST00000304032 / NM_001037131.3; = p.A661V on NM_014914.5) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100366763; called by muse, mutect2, varscan2
- ALDH1L2 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311259; called by muse, mutect2, varscan2
- ANKRD30A | c.3157G>T p.G1053* (on ENST00000611781; = p.G997* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100654144, COSV100654257; called by muse, mutect2, varscan2
- APOBR | c.2807G>T p.G936V (on ENST00000431282; = p.G945V on NM_018690.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100112827; called by muse, mutect2, varscan2
- APP | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100696184; called by muse, mutect2, varscan2
- ARL6IP5 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV56235683, COSV99833029; called by muse, mutect2, varscan2
- ARPC5 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as COSV99664920; called by muse, mutect2, varscan2
- ARX | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100984079; called by muse, mutect2, varscan2
- ATP13A5 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100665594; called by muse, mutect2, varscan2
- ATP8A2 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99683693; called by muse, mutect2, varscan2
- ATP9A | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.212); catalogued as rs759279499, COSV58766844; called by muse, mutect2, varscan2
- B3GALT1 | c.302G>C p.W101S | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465681499, COSV100003016; called by muse, mutect2, varscan2
- BCKDHB | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100243965; called by muse, varscan2
- BSN | c.9245C>T p.T3082I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV99609545; called by muse, varscan2
- CACNA1H | c.6791C>T p.P2264L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV52358430; called by muse, mutect2, varscan2
- CADM3 | c.430G>A p.E144K (on ENST00000368125 / NM_001127173.3; = p.E178K on NM_021189.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684053; called by muse, mutect2, varscan2
- CALHM1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs750504998, COSV53296340, COSV99588783; called by muse, mutect2, varscan2
- CCDC114 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1314644286, COSV100196398; called by muse, mutect2, varscan2
- CCDC39 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869036, COSV99870314; called by muse, mutect2
- CCDC63 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100370565; called by muse, varscan2
- CCNT1 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99980874; called by muse, mutect2, varscan2
- CD163L1 | c.3100A>T p.K1034* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100550575; called by muse, mutect2, varscan2
- CDON | c.3441G>T p.L1147F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99701840; called by muse, mutect2, varscan2
- CFTR | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397508271, CM034786, COSV99138760; called by muse, mutect2, varscan2
- CMYA5 | c.11777G>T p.R3926I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101405690; called by muse, mutect2, varscan2
- CNOT6L | c.768G>T p.E256D (on ENST00000504123 / NM_001286790.2; = p.E251D on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53696949, COSV99361248; called by muse, mutect2, varscan2
- CNTN1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as COSV100751830; called by muse, mutect2, varscan2
- COL9A1 | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100295383; called by muse, mutect2, varscan2
- COPB1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99999850; called by muse, mutect2, varscan2
- CPNE3 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99547741, COSV99547989; called by muse, mutect2, varscan2
- CPNE6 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99393675; called by muse, mutect2, varscan2
- CR2 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100889692; called by muse, mutect2, varscan2
- CR2 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100889693; called by muse, mutect2, varscan2
- CRYBG1 | c.5200G>A p.E1734K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV64812362; called by muse, mutect2
- CSMD2 | c.3194G>A p.C1065Y | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594108; called by muse, mutect2, varscan2
- CSMD2 | c.1191G>T p.R397S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV99594113; called by muse, mutect2
- CSTF2T | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100484294; called by muse, mutect2, varscan2
- CTNNA2 | c.2663C>T p.T888I (on ENST00000402739 / NM_001282597.3; = p.T840I on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561791; called by muse, mutect2, varscan2
- CYP4F8 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100358206; called by muse, mutect2, varscan2
- DENND2A | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as COSV99326814; called by muse, mutect2, varscan2
- DENND4B | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100768855; called by muse, mutect2, varscan2
- DENND4B | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs751840276, COSV63409361; called by muse, mutect2, varscan2
- DHRS4L2 | c.71T>A p.M24K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as COSV100632607; called by muse, mutect2
- DLX2 | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs201345810, COSV99308650; called by muse, mutect2, varscan2
- EPHB1 | c.1973C>A p.S658* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV101214077; called by muse, mutect2, varscan2
- EXOSC5 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99524724; called by muse, mutect2, varscan2
- F13B | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100803401, COSV66373146; called by muse, mutect2, varscan2
- FAAH2 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs755102177, COSV100887419; called by muse, mutect2, varscan2
- FAT1 | c.9721G>C p.E3241Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499590; called by muse, mutect2, varscan2
- FBXL13 | c.1262T>G p.I421R | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100502001; called by muse, mutect2, varscan2
- FERD3L | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as COSV51762173, COSV99285055; called by muse, mutect2, varscan2
- FHDC1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV99471612; called by muse, mutect2, varscan2
- FMR1 | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99503708; called by muse, mutect2, varscan2
- FNDC8 | c.867C>A p.Y289* | Nonsense Mutation (SNP) | VAF 35/71 reads (49%) | catalogued as COSV99338993; called by muse, mutect2, varscan2
- GABRA1 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99196201; called by muse, mutect2, varscan2
- GABRA5 | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100165628; called by muse, mutect2, varscan2
- GPAM | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100788374; called by muse, mutect2
- GPR149 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV67667000; called by muse, mutect2, varscan2
- GPR161 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99607078; called by muse, mutect2, varscan2
- GRM5 | c.2392A>G p.K798E | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100553917; called by muse, mutect2, varscan2
- GULP1 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100771059; called by muse, mutect2, varscan2
- HCN1 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV57544388; called by muse, mutect2, varscan2
- HDAC9 | c.2362A>T p.T788S | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV101287066; called by muse, mutect2, varscan2
- HGFAC | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100123247; called by muse, mutect2, varscan2
- HJV | c.1019T>C p.I340T (on ENST00000336751 / NM_213653.4; = p.I227T on NM_145277.5) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1553769422, COSV100382374; called by muse, mutect2, varscan2
- HNF4A | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV100291673, COSV100291797; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as rs756867438, COSV54190263, COSV99523841; called by muse, mutect2, varscan2
- HTR2C | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV99350576; called by muse, mutect2, varscan2
- HYAL4 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99772419; called by muse, mutect2, varscan2
- IFNA16 | c.187del p.Q63Rfs*21 | Frame Shift Del (DEL) | VAF 78/284 reads (27%) | catalogued as rs1563816409; called by mutect2, pindel, varscan2
- IL17C | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99733376; called by muse, mutect2, varscan2
- IPO13 | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV100960936; called by muse, mutect2, varscan2
- KHDC4 | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100850845; called by muse, mutect2, varscan2
- KIAA1109 | c.5037+1G>A p.X1679_splice | Splice Site (SNP) | VAF 45/80 reads (56%) | catalogued as COSV99170120; called by muse, mutect2, varscan2
- KIR3DL2 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99552279; called by muse, mutect2, varscan2
- KIT | c.1633T>C p.Y545H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855113; called by muse, mutect2
- KLHL28 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61889058; called by muse, varscan2
- KLHL36 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.379); catalogued as COSV99257029; called by muse, mutect2, varscan2
- KRT83 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1040745810, COSV99531851; called by muse, mutect2, varscan2
- KRTAP10-5 | c.814T>A p.*272Rext*11 | Nonstop Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100555115; called by muse, mutect2, varscan2
- L3MBTL1 | c.943T>C p.F315L (on ENST00000418998 / NM_001377303.1; = p.F225L on NM_015478.7) | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917040; called by muse, mutect2, varscan2
- LAMA4 | c.4108T>A p.C1370S (on ENST00000230538 / NM_001105206.3; = p.C1363S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039203; called by muse, mutect2, varscan2
- LCT | c.2475C>A p.S825R | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.938); catalogued as COSV99930250; called by muse, mutect2, varscan2
- LEPR | c.369A>T p.I123= | Splice Region (SNP) | VAF 31/59 reads (53%) | catalogued as COSV100756726; called by muse, mutect2, varscan2
- LLGL1 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100375592, COSV57499177; called by muse, mutect2, varscan2
- LMF1 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as COSV99235803; called by muse, mutect2
- LRRC28 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 15/142 reads (11%) | catalogued as COSV100113799; called by muse, mutect2, varscan2
- LRRC8A | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV99396863; called by muse, mutect2, varscan2
- LRRTM4 | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69143237; called by muse, mutect2, varscan2
- MAGEB3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV100854785; called by muse, varscan2
- MASP1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs1335410378, COSV99397577; called by muse, mutect2, varscan2
- MED10 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 71/155 reads (46%) | catalogued as COSV99740385; called by muse, mutect2, varscan2
- MED31 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV99854618; called by muse, mutect2
- METTL9 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV100820616; called by muse, mutect2, varscan2
- MGAM | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV101516517; called by muse, mutect2, varscan2
- MLH3 | c.2624C>G p.S875C | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs760079290, COSV99470589; called by muse, mutect2, varscan2
- MME | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100852501; called by muse, mutect2, varscan2
- MORC1 | c.1856G>A p.R619K | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs758608795, COSV99227469; called by muse, mutect2, varscan2
- MSH4 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV99592317; called by muse, mutect2, varscan2
- MTOR | c.6628G>C p.A2210P | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.599); catalogued as COSV63870065; called by muse, mutect2, varscan2
- MTUS2 | c.2381C>A p.A794E | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV101462339, COSV70916698; called by muse, mutect2, varscan2
- MUC16 | c.25805C>A p.T8602K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.842); catalogued as COSV101201100; called by muse, mutect2, varscan2
- MUC16 | c.8171C>T p.P2724L | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67443221; called by muse, mutect2, varscan2
- MYH1 | c.5443C>G p.Q1815E | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV99876668; called by muse, mutect2
- MYH15 | c.479A>T p.Y160F | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1165863212, COSV99844104; called by muse, mutect2, varscan2
- MYOM2 | c.1372A>T p.R458W | Missense Mutation (SNP) | VAF 134/246 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100038185; called by muse, mutect2, varscan2
- NAA16 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 42/74 reads (57%) | catalogued as COSV101050148; called by muse, mutect2, varscan2
- NCOA1 | c.3408G>C p.R1136S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56055752, COSV99946833; called by muse, mutect2, varscan2
- NCOA6 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV100750269; called by muse, mutect2, varscan2
- NLGN4X | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 89/150 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52012135, COSV99323501; called by muse, mutect2, varscan2
- NLGN4X | c.1969G>T p.G657W | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52031778; called by muse, mutect2, varscan2
- NLRP13 | c.2506A>T p.S836C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100738439; called by muse, mutect2, varscan2
- NME8 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52257602, COSV99553734; called by muse, mutect2, varscan2
- NOS1 | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV100501263; called by muse, mutect2, varscan2
- NOTCH3 | c.1298A>C p.N433T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658524; called by muse, mutect2, varscan2
- NRSN1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867401260, COSV101027358; called by muse, mutect2, varscan2
- NTRK3 | c.2213C>A p.P738H (on ENST00000360948 / NM_001012338.2; = p.P724H on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100713626; called by muse, mutect2
- NTRK3 | c.2212C>A p.P738T (on ENST00000360948 / NM_001012338.2; = p.P724T on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100713627; called by muse, mutect2
- OCA2 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100668494, COSV62358899; called by muse, mutect2, varscan2
- OR10T2 | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100555073; called by muse, mutect2, varscan2
- OR2AG1 | c.151A>G p.M51V | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1330598911, COSV100264950; called by muse, mutect2, varscan2
- OR2L13 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV100813867; called by muse, mutect2, varscan2
- OR2M4 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV100141467; called by muse, mutect2, varscan2
- OR2T27 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100788355; called by muse, mutect2, varscan2
- OR2W1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV101013936; called by muse, mutect2, varscan2
- OR4D10 | c.479T>A p.I160N | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101597022; called by muse, mutect2, varscan2
- OR4N5 | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 233/370 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100374197, COSV61321412; called by muse, mutect2, varscan2
- OR5B12 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as rs1480040385, COSV100222529; called by muse, mutect2, varscan2
- OR6C75 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100595426; called by muse, mutect2, varscan2
- OR6K2 | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV100656859, COSV62743146; called by muse, mutect2, varscan2
- OR8I2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100136231; called by muse, varscan2
- OR8K5 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as rs756396007, COSV100537298; called by muse, mutect2, varscan2
- OTUD7A | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100193069; called by muse, mutect2, varscan2
- PARD3B | c.2185+1G>T p.X729_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100594835; called by muse, mutect2, varscan2
- PCDHA3 | c.2386T>A p.S796T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV100793684; called by muse, mutect2, varscan2
- PCYT2 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100155694; called by muse, mutect2, varscan2
- PEX2 | c.314G>C p.W105S | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.224); catalogued as COSV63814455; called by muse, mutect2, varscan2
- PIGT | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99649170; called by muse, mutect2, varscan2
- PKD2L2 | c.526T>C p.W176R | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99296614; called by muse, mutect2, varscan2
- PNPLA1 | c.1506G>T p.K502N (on ENST00000394571 / NM_001374623.1; = p.K407N on NM_173676.2) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV57239290; called by muse, mutect2, varscan2
- POU4F1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV101020540; called by muse, mutect2, varscan2
- PPIC | c.575C>G p.S192W | Missense Mutation (SNP) | VAF 130/256 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100120614; called by muse, mutect2, varscan2
- PPP1R36 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 124/324 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.066); catalogued as COSV100073007; called by muse, varscan2
- PRKCH | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100273676; called by muse, mutect2, varscan2
- PSMB8 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100841283; called by muse, mutect2, varscan2
- PTPRJ | c.1934G>T p.W645L | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101395709; called by muse, mutect2, varscan2
- PZP | c.4436A>T p.H1479L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99739088; called by muse, mutect2, varscan2
- QTRT2 | c.48A>T p.K16N | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99847021; called by muse, mutect2, varscan2
- QTRT2 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV99847023; called by muse, mutect2, varscan2
- RABGGTA | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99253181; called by muse, varscan2
- RASA1 | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | catalogued as COSV57200659; called by muse, mutect2, varscan2
- RELN | c.4294G>T p.G1432* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100634581, COSV100634933; called by muse, mutect2, varscan2
- RFX4 | c.1556C>A p.A519D (on ENST00000392842 / NM_213594.3; = p.A425D on NM_032491.6) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57572912, COSV99986232; called by muse, mutect2, varscan2
- RGS12 | c.1804T>G p.W602G | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV100376202; called by muse, mutect2, varscan2
- RGS17 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99243316; called by muse, mutect2
- RNF217 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.402); catalogued as rs771857682, COSV101451423; called by muse, varscan2
- ROBO1 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101459161; called by muse, mutect2, varscan2
- ROBO3 | c.3225G>T p.Q1075H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV101185154; called by muse, mutect2
- ROPN1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99481537; called by mutect2, varscan2
- ROR1 | c.609A>G p.T203= | Splice Region (SNP) | VAF 39/93 reads (42%) | catalogued as COSV100935493; called by muse, mutect2, varscan2
- RPA4 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV100234646; called by muse, mutect2, varscan2
- SCN9A | c.1903T>A p.S635T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV100313869; called by muse, mutect2, varscan2
- SEC16B | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1484832506, COSV100381255, COSV100381860; called by muse, mutect2, varscan2
- SEL1L2 | c.2045T>G p.L682W | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99533771; called by muse, mutect2, varscan2
- SETD2 | c.5540A>G p.N1847S | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as COSV100339801; called by muse, mutect2, varscan2
- SGIP1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 124/323 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV52779839; called by muse, mutect2, varscan2
- SHROOM4 | c.1315G>T p.V439L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV99174324; called by muse, mutect2, varscan2
- SLC17A6 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV54135173; called by muse, mutect2
- SLC24A4 | c.1770C>A p.Y590* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100105913; called by muse, mutect2, varscan2
- SLC29A4 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.214); catalogued as COSV99786912; called by muse, mutect2, varscan2
- SLCO1A2 | c.1024T>A p.Y342N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100262514; called by muse, mutect2, varscan2
- SLFN5 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100249782; called by muse, mutect2, varscan2
- SLITRK3 | c.1778G>T p.S593I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99579904; called by muse, mutect2, varscan2
- SLX4 | c.520A>G p.R174G | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs775195965, COSV99568421; called by muse, mutect2, varscan2
- SMYD1 | c.533A>T p.N178I | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV101352502; called by muse, mutect2, varscan2
- SPATA19 | c.213G>C p.M71I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100141242; called by muse, mutect2, varscan2
- SPEG | c.8629C>T p.L2877F | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as rs757207859, COSV100405394; called by muse, mutect2, varscan2
- SPTBN4 | c.1520C>A p.A507E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.182); catalogued as COSV100151842; called by muse, mutect2, varscan2
- SPTBN5 | c.3641G>T p.G1214V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100312058; called by muse, mutect2, varscan2
- ST18 | c.3050C>A p.T1017K | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99390770; called by muse, mutect2, varscan2
- ST18 | c.3049A>C p.T1017P | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99389600; called by muse, mutect2, varscan2
- SUCO | c.3016del p.E1006Rfs*21 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV99742186; called by mutect2, pindel, varscan2
- SYMPK | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55609691, COSV99842011, COSV99842029; called by muse, mutect2, varscan2
- SYMPK | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.137); catalogued as COSV99842012; called by muse, mutect2, varscan2
- SYNE1 | c.10031G>A p.G3344E (on ENST00000367255 / NM_182961.4; = p.G3351E on NM_033071.3) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575354, COSV99575436; called by muse, mutect2, varscan2
- SYNE1 | c.9892G>T p.D3298Y (on ENST00000367255 / NM_182961.4; = p.D3305Y on NM_033071.3) | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99575439; called by muse, mutect2, varscan2
- SYNE1 | c.4562G>C p.R1521P (on ENST00000367255 / NM_182961.4; = p.R1528P on NM_033071.3) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs149606474, COSV99575446; called by muse, mutect2, varscan2
- SYT5 | c.826+1G>A p.X276_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100845940; called by muse, mutect2, varscan2
- TENM1 | c.4621G>T p.D1541Y | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100950640; called by muse, mutect2, varscan2
- TMPRSS15 | c.2803C>A p.L935I | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53043885, COSV99518993; called by muse, mutect2, varscan2
- TMPRSS3 | c.1085T>A p.V362D | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368563; called by muse, mutect2, varscan2
- TPR | c.1601C>G p.S534* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as COSV100824214, COSV66603174; called by muse, mutect2, varscan2
- TRIM48 | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1007971880, COSV101338344; called by muse, mutect2, varscan2
- TRIM51 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55269118, COSV99792579; called by muse, mutect2
- TRIML1 | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100206239; called by muse, mutect2, varscan2
- TRPA1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100084979; called by muse, mutect2, varscan2
- TRPC3 | c.1993A>T p.M665L (on ENST00000379645 / NM_001366479.2; = p.M592L on NM_003305.2) | Missense Mutation (SNP) | VAF 145/251 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.405); catalogued as COSV99313356; called by muse, mutect2, varscan2
- TRPM3 | c.3523G>A p.D1175N (on ENST00000357533 / NM_001366142.2; = p.D1030N on NM_020952.6) | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1349694731, COSV100678421; called by muse, mutect2, varscan2
- TTN | c.94661A>C p.Q31554P (on ENST00000591111; = p.Q24130P on NM_003319.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | PolyPhen probably damaging (0.993); catalogued as COSV100625987; called by muse, mutect2, varscan2
- TTN | c.94660C>A p.Q31554K (on ENST00000591111; = p.Q24130K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | PolyPhen probably damaging (0.948); catalogued as COSV100625988; called by muse, mutect2, varscan2
- TTN | c.81703C>T p.P27235S (on ENST00000591111; = p.P19811S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | PolyPhen benign (0.073); catalogued as rs1322696753, COSV100625991; called by muse, mutect2
- TTN | c.47565T>A p.D15855E (on ENST00000591111; = p.D8431E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen probably damaging (0.945); catalogued as rs1227243648, COSV100625993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2431A>G p.T811A (on ENST00000591111; = p.T765A on NM_003319.4) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | PolyPhen possibly damaging (0.879); catalogued as COSV100625994; called by muse, mutect2, varscan2
- TUT4 | c.4862C>T p.T1621I | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV99932728; called by muse, mutect2, varscan2
- UGT2B28 | c.1464C>A p.Y488* | Nonsense Mutation (SNP) | VAF 53/118 reads (45%) | catalogued as COSV100158568; called by muse, mutect2, varscan2
- UGT2B28 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100158725, COSV100158991; called by muse, mutect2, varscan2
- USH2A | c.5778A>G p.E1926= | Splice Region (SNP) | VAF 51/198 reads (26%) | catalogued as COSV100240718; called by muse, mutect2, varscan2
- UTP18 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99834916; called by muse, mutect2, varscan2
- WAC | c.1649G>C p.R550P | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.578); catalogued as COSV100610837, COSV100611167; called by muse, mutect2, varscan2
- YIPF4 | c.637T>G p.L213V | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV99480036; called by muse, mutect2, varscan2
- ZADH2 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV100463533; called by muse, mutect2, varscan2
- ZBTB32 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99386218; called by muse, mutect2
- ZEB1 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV100314864; called by muse, mutect2, varscan2
- ZNF335 | c.1730T>G p.L577R | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533300; called by muse, mutect2, varscan2
- ZNF407 | c.5570C>G p.A1857G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100226781; called by muse, mutect2
- ZNF518A | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100283615, COSV100283689; called by muse, mutect2
- ZNF611 | c.597G>T p.R199S | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs750311214, COSV60543747; called by muse, mutect2, varscan2
- ZNF611 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.558); catalogued as COSV100160528; called by muse, mutect2, varscan2
- ZNF700 | c.1795A>G p.K599E | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99583744; called by muse, mutect2, varscan2
- ZNF804A | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs771561584, COSV56475647; called by muse, mutect2, varscan2
- ZNF804A | c.2162C>A p.T721N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs546110129, COSV100169650; called by muse, mutect2, varscan2
- ZSCAN9 | c.142A>T p.R48W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99356556; called by muse, mutect2, varscan2
- CWF19L2 | c.1176_1177del p.A394Ifs*9 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- FLT1 | c.3328del p.C1110Afs*4 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.642C>G p.H214Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.193); called by mutect2, varscan2
- HGD | c.902dup p.L301Ffs*4 | Frame Shift Ins (INS) | VAF 29/167 reads (17%) | called by mutect2, pindel, varscan2
- IKZF1 | c.1318_1319del p.A440Rfs*48 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- MRC1 | c.2944G>T p.G982W | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NELFA | c.1287_1288del p.Q429Hfs*10 (on ENST00000542778; = p.Q418Hfs*10 on NM_005663.5) | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.1548_1549del p.Q517Afs*6 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by pindel, varscan2
- PIK3R1 | c.1685_1705del p.R562_D569delinsH (on ENST00000521381 / NM_181523.3; = p.R292_D299delinsH on NM_181504.4) | In Frame Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 171/354 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ROS1 | c.3201del p.F1067Lfs*13 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | called by mutect2, pindel, varscan2
- RYR1 | c.8914_8916del p.E2972del | In Frame Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- TSGA10IP | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AHNAK | c.13773G>A p.P4591= | Silent (SNP) | VAF 98/259 reads (38%) | catalogued as rs1207343719, COSV99948881; called by muse, mutect2, varscan2
- ALDH4A1 | c.1287G>A p.V429= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV99312050, COSV99312245; called by muse, mutect2, varscan2
- ANKRD30A | c.624C>A p.A208= (on ENST00000611781; = p.A152= on NM_052997.2) | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV100654255; called by muse, mutect2, varscan2
- APPBP2 | c.1647G>A p.R549= | Silent (SNP) | VAF 151/369 reads (41%) | catalogued as COSV99319836; called by muse, mutect2, varscan2
- CC2D1A | c.2556G>A p.A852= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as rs779247588, COSV99583045; called by muse, mutect2, varscan2
- CDH10 | c.777G>T p.L259= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV100052735; called by muse, mutect2, varscan2
- CILP | c.2697C>A p.L899= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV56026848, COSV99973836; called by muse, mutect2
- CNTNAP5 | c.570G>C p.L190= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV101443969; called by muse, mutect2, varscan2
- CPS1 | c.627C>A p.V209= | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as COSV51823499; called by muse, mutect2, varscan2
- CUBN | c.5190G>C p.T1730= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100913376; called by mutect2, varscan2
- CYP11B1 | c.483G>T p.V161= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV99455570; called by muse, mutect2, varscan2
- DDC | c.24G>A p.R8= | Silent (SNP) | VAF 77/214 reads (36%) | catalogued as rs74987565, COSV63565308; called by muse, mutect2, varscan2
- DEFB112 | c.111G>C p.A37= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs267601068, COSV100452179; called by muse, mutect2, varscan2
- EIF3E | c.1326T>C p.S442= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99623431; called by muse, mutect2, varscan2
- EPHA7 | c.1131C>A p.G377= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV65184907; called by muse, mutect2, varscan2
- ERC1 | c.3099C>T p.L1033= (on ENST00000360905 / NM_178040.4; = p.L1005= on NM_178039.4) | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- ETV5 | c.1119C>T p.F373= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100112545; called by muse, mutect2, varscan2
- EVI5 | c.1389A>G p.L463= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV100945464; called by muse, mutect2, varscan2
- EXOSC3 | c.429C>T p.Y143= | Silent (SNP) | VAF 69/180 reads (38%) | catalogued as rs781685540, COSV53051697; called by muse, mutect2, varscan2
- FAM76A | c.480T>C p.Y160= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV99159612; called by muse, mutect2, varscan2
- FHDC1 | c.570G>T p.R190= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV99471616; called by muse, mutect2, varscan2
- FOLH1 | c.2004C>A p.L668= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV99923738; called by muse, mutect2, varscan2
- FRMD5 | c.867G>A p.E289= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV68720474; called by muse, mutect2
- GIGYF1 | c.2775A>C p.V925= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV99309871; called by muse, mutect2, varscan2
- GRIA1 | c.2553C>T p.N851= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs771436134, COSV53589376; called by muse, mutect2, varscan2
- HARS1 | c.750G>A p.K250= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as COSV100298231; called by muse, mutect2, varscan2
- KRT83 | c.483T>G p.A161= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as rs1009536233, COSV99531846; called by muse, mutect2, varscan2
- L3MBTL1 | c.942C>T p.L314= (on ENST00000418998 / NM_001377303.1; = p.L224= on NM_015478.7) | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV100917038; called by muse, mutect2, varscan2
- MTMR9 | c.660G>A p.L220= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99644521; called by muse, mutect2, varscan2
- OR2M5 | c.237C>T p.P79= | Silent (SNP) | VAF 90/355 reads (25%) | catalogued as COSV100822819, COSV100822863; called by muse, mutect2, varscan2
- OR4L1 | c.627C>A p.T209= | Silent (SNP) | VAF 231/402 reads (57%) | catalogued as COSV100235866, COSV59848953; called by muse, mutect2, varscan2
- PCDHA5 | c.1680C>T p.N560= | Silent (SNP) | VAF 58/113 reads (51%) | catalogued as rs781952897, COSV100972487, COSV65349512; called by muse, mutect2, varscan2
- PEG3 | c.1506G>A p.G502= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as COSV99690080; called by muse, mutect2, varscan2
- PLA2G2E | c.258C>T p.F86= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs1450420106, COSV100908828; called by muse, mutect2, varscan2
- PPP1R9A | c.2898C>T p.D966= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as rs578242138, COSV99197795; called by muse, mutect2, varscan2
- PRKDC | c.7053A>G p.Q2351= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as rs1245355127, COSV100042378; called by muse, mutect2, varscan2
- PTPN6 | c.298C>T p.L100= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100017239; called by muse, mutect2, varscan2
- SLC24A5 | c.1359T>C p.F453= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV99982028; called by muse, mutect2, varscan2
- SMYD3 | c.1173G>A p.K391= (on ENST00000490107 / NM_001375962.1; = p.K332= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1387643826, COSV100830884; called by muse, mutect2
- TIMP4 | c.108C>T p.H36= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV99826087; called by muse, mutect2, varscan2
- TNXB | c.8229G>C p.V2743= (on ENST00000647633; = p.V2496= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100926559; called by muse, mutect2
- TSGA10IP | c.606G>T p.G202= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.70641T>C p.N23547= (on ENST00000591111; = p.N16123= on NM_003319.4) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100625992; called by muse, mutect2, varscan2
- UNC13C | c.915C>T p.I305= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV52926848; called by muse, mutect2, varscan2
- UPRT | c.645A>T p.T215= | Silent (SNP) | VAF 84/114 reads (74%) | catalogued as rs1411828628, COSV100975849; called by muse, mutect2, varscan2
- UTS2 | c.174G>A p.E58= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as rs1314668979, COSV99276894; called by muse, mutect2, varscan2
- ZNF157 | c.474A>T p.G158= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV100998522; called by muse, mutect2, varscan2
- ZNF804A | c.579T>C p.Y193= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs757422376, COSV100169648; called by muse, mutect2, varscan2
- EEF1B2 | c.331-106G>A | Intron (SNP) | VAF 52/160 reads (33%) | catalogued as rs777692143, COSV99261337; called by muse, mutect2, varscan2
- H2BP2 | n.1062-372G>T | Intron (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1146C>T | RNA (SNP) | VAF 11/27 reads (41%) | catalogued as rs1439959295; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847184 G>T | 5'Flank (SNP) | VAF 78/249 reads (31%) | catalogued as rs1432717852; called by muse, mutect2, varscan2
- PDLIM5 | c.920+551G>C | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100524255; called by muse, mutect2, varscan2
- SNORD115-42 | n.59C>T | RNA (SNP) | VAF 151/381 reads (40%) | called by muse, mutect2, varscan2
- WNT3A | c.-2C>T | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99470061; called by muse, mutect2, varscan2
